CPTAC case C3L-02649 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b8f09d8d-2806-4d9a-b44c-8c949bc30e38

Demographics
Sex at birth: male; Race: white; Year of birth: 1955; Vital status: Dead; Days to death: 1,072 days (2.9 years); Year of death: 2021; Cause of death: Cancer Related; Country of birth: Bulgaria.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 62.3 years (22,773 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T4; AJCC pathologic N: N2a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 1,072 days (2.9 years); Progression or recurrence: no; Days to last follow up: 1,019 days (2.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 8.8 cm; Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 16; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (3 entries)
- Days to follow up: 483 days (1.3 years); Disease response: With Tumor; ECOG performance status: 1.
- Days to follow up: 810 days (2.2 years); Disease response: With Tumor; ECOG performance status: 2.
- Days to follow up: 1,019 days (2.8 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 235 days; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 93 kg; Height: 200 cm; BMI: 23.25; FEV1 before bronchodilator (% of reference): 85.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Cigarettes per day: 40; Tobacco smoking quit year: 2004; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02649-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 522 mg; Time between clamping and freezing: 28 minutes; Time between excision and freezing: 13 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02649-24: Section location: Left Lower Lobe; Percent tumor nuclei: 65; Percent necrosis: 20.
- Sample C3L-02649-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 306 mg; Time between clamping and freezing: 30 minutes; Time between excision and freezing: 15 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02649-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
